Surgical pathology report (de-identified scan), TCGA case TCGA-AK-3451, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-AK-3451-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Clinical History/Diagnosis: Left Renal Tumor

Source of Specimen(s):

- 1: left Kidney resection with Adrenal gland
- 2: left paraaortic lymph nodes

Gross Description:

Received in two parts.

Source of Tissue: 1. Labeled # 1, "left kidney with mass, portion of adrenal and hilar lymph node"

Frozen Section Diagnosis: 1FS- RENAL CELL CARCINOMA

Gross Description: Received fresh in a container labeled ", left kidney with mass, portion of adrenal and hilar lymph node". It consists of a 720 gram left radical nephrectomy consisting of left kidney measuring 15.0 x 8.0 x 7.0 cm with attached fat ranging from 0.1 up to 3.5 cm from point of attachment. At the hilum the segment of ureter measures 9.0 x 0.5 cm with a pin point lumen and no suspicious areas. The vessels are also normal. At the superior aspect of the hilum there is a portion of adrenal gland measuring 2.8 x 1.5 x 0.4 cm. The adrenal gland is normal. The kidney is bivalved disclosing a large soft mass centrally in the kidney that measures 9.0 x 6.0 x 7.0 cm. The kidney is orangish yellow to red in color and centrally within the mass is a large cyst containing gelatinous, necrotic material. The tumor comprises approximately 60% of the nephrectomy and markedly distorts the calyceal system. The mass is pushing on the capsule in multiple areas however no gross invasion is found. Multiple representative sections of the tumor in relationship to the capsule and overlying fat will be submitted for histological impression. Elsewhere, adjacent to the tumor the kidney is normal appearing with the usual cortical-medullary junctions. Dissection through the fat and the hilum discloses moist glistening adipose tissue and no nodal tissue is found. Fresh tissue is procured and sent for Cytogenetics and Gross Photos are taken.

Designation of Sections: 1A- vascular and ureter margins, 1B- adrenal gland, 1C- tumor pushing on hilum, 1D-1E- tumor pushing on pelvis, 1F-1H- tumor in relationship to capsule and fat, 1I-1J- tumor in relationship to adjacent normal parenchyma, 1K-1L- perinephric fat

Source of Tissue: 2. Labeled # 2, "left para aortic lymph nodes"

Gross Description: Received fresh in a container labeled " left para aortic lymph nodes".

It consists of multiple

fragments of fibroadipose tissue measuring 4.0 x 4.0 x 1.5 cm. Dissection through the tissue discloses a few normal appearing and fatty nodes ranging from 0.1 up to 2.5 cm.

[page 2 of 2]
Designation of Sections: 2A-2D- multiple single lymph nodes and fat, 2E- single bisected lymph node, 2F- single bisected node

Final Diagnosis:

1. Kidney and adrenal, left, radical nephrectomy and partial adrenalectomy:

- Renal cell carcinoma, conventional type, Fuhrman grade III (9 cm).
- The tumor appears confined to the kidney.
- Adrenal gland, No tumor seen.

Note: The tumor shows admixed areas of low grade clear cell carcinoma, and higher grade tumor with abundant granular cytoplasm (both can be seen in conventional type renal cell carcinoma).

2. Left para aortic lymph nodes, excision:

- No tumor seen in sixteen lymph nodes (0/16).

- pT2N0Mx

FCGTL: Chromo15, Chrom45, Interp

Procedures/Addenda

FC Cytogenetics Solid Tumor

Interpretation

CYTOGENETIC ANALYSIS REPORTS

DIAGNOSIS: Clear Cell Renal Cell Carcinoma

KARYOTYPE: Abnormal mosaic male karyotype:

38

44,XY,del(3)(p13),+mar[cp4]/46,XY[13]

RESULTS: The renal tumor was harvested after six and eleven days in culture. Seventeen metaphases were found in a scan of twelve slides. The chromosomes from these metaphases were counted and analyzed, and four of these metaphases were karyotyped by G-banding. Four cells had between 38 and 44 chromosomes and contained a deletion in the p arm of chromosome 3 as well as a marker chromosome. Thirteen cells had a modal chromosome number of 46 and appeared to have a normal karyotype. The deletion in 3p is characteristic of clear cell renal cell carcinoma.

Source: NCI Genomic Data Commons file c4cd5092-4437-4486-8113-31b830cb006a (TCGA-AK-3451.D6215E63-5074-470C-8FE0-303B61E3C25A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).